Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A017, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A017-01A (Primary Tumor).

Sample ID #. . .

Diagnosis:

Resected colon with an extensive, ulcerated, moderately differentiated adenocarcinoma of the colorectal type with infiltration of the pericolic fatty tissue, and measuring a max of 3.5 cm. Tumor-free local lymph nodes. Tumor-free colon resection margins. Tumor-free mesocolic amputation margin.

Tumor classification: pT3 pN0 (0/18), pMX; G2, L1, V0, R0.

1CD-0-3

adenocarcinoma, NOS 8140/3

Site: sigmoid colon (per CQCF) C18.7

hr 3/30/11

Reason for Disqualification:	Kmt hr 5/10/11	

Source: NCI Genomic Data Commons file fb764850-421a-4584-b10e-5cc6e7e775de (TCGA-AA-A017.6DFB118D-B692-4957-B563-B3A91080038F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).